Somatic mutation profile of tumor specimen TCGA-A5-A2K2-01A (aliquot TCGA-A5-A2K2-01A-11D-A18P-09) from TCGA case TCGA-A5-A2K2, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 77.9 years (28,456 days).
Specimen TCGA-A5-A2K2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) db7a9e57-ccdc-4f3e-9bbd-1dd445d267e5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A5-A2K2-10A (Blood Derived Normal), aliquot TCGA-A5-A2K2-10A-01D-A18P-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bcd194c4-10f9-473a-909b-2a48af99b382

The open-access MAF lists 135 somatic variants for this specimen: 106 protein-altering or splice-affecting, 27 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 89, Silent 27, Nonsense Mutation 9, Splice Site 4, Frame Shift Del 3, In Frame Ins 1, 5'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACE2 | c.802+1G>T p.X268_splice | Splice Site (SNP) | VAF 13/24 reads (54%) | catalogued as rs949916988, COSV99382785; called by muse, mutect2, varscan2
- ACTR1B | c.496C>G p.H166D | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100008092; called by mutect2, varscan2
- ADAMTS18 | c.3280C>T p.R1094* | Nonsense Mutation (SNP) | VAF 19/23 reads (83%) | catalogued as rs775431905, COSV51417329; called by muse, mutect2, varscan2
- AFAP1L1 | c.1877A>C p.K626T | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99695885; called by muse, mutect2, varscan2
- AHNAK | c.154+2T>A p.X52_splice | Splice Site (SNP) | VAF 8/31 reads (26%) | catalogued as COSV99947354; called by muse, mutect2, varscan2
- ARHGEF11 | c.2991G>C p.Q997H | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV100168586; called by muse, mutect2, varscan2
- ATP2B1 | c.823G>A p.V275I | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); catalogued as COSV99665663; called by muse, mutect2
- BTBD3 | c.1169A>G p.Y390C | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV99655861; called by muse, mutect2, varscan2
- C11orf71 | c.235G>A p.D79N | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.484); catalogued as rs1051890, COSV100348338, COSV57784357; called by muse, mutect2, varscan2
- C7 | c.2093C>G p.A698G | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV100495777, COSV57473572; called by muse, mutect2
- CAMK2B | c.1700C>A p.S567* | Nonsense Mutation (SNP) | VAF 12/71 reads (17%) | catalogued as COSV99323036; called by muse, mutect2, varscan2
- CASQ2 | c.839-1G>C p.X280_splice | Splice Site (SNP) | VAF 12/47 reads (26%) | catalogued as rs1336110482, COSV99797474; called by muse, mutect2, varscan2
- CFAP57 | c.1552A>G p.I518V | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as COSV65264318; called by muse, mutect2, varscan2
- CNTRL | c.6764G>C p.C2255S | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV99442291; called by mutect2, varscan2
- COL3A1 | c.1265A>C p.N422T | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100482997; called by muse, mutect2
- CP | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV52830351, COSV99224097; called by muse, mutect2
- CXorf65 | c.198C>G p.Y66* | Nonsense Mutation (SNP) | VAF 4/70 reads (6%) | catalogued as COSV99340196; called by muse, mutect2
- DCC | c.1231A>G p.T411A | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59114561; called by muse, mutect2
- DEGS1 | c.566A>G p.N189S | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV100083358; called by muse, mutect2, varscan2
- DPF3 | c.478G>T p.D160Y | Missense Mutation (SNP) | VAF 28/149 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.67); catalogued as COSV100818554; called by muse, mutect2, varscan2
- EGF | c.2324C>A p.S775* | Nonsense Mutation (SNP) | VAF 18/70 reads (26%) | catalogued as COSV99490894; called by muse, mutect2, varscan2
- ERN2 | c.1228C>T p.L410F | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.067); catalogued as rs55687638, COSV99891486; called by muse, mutect2, varscan2
- FARP1 | c.477G>C p.L159F | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV100130632; called by muse, varscan2
- FBXW11 | c.1529A>G p.H510R | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); catalogued as COSV99440421; called by muse, mutect2, varscan2
- FOXI1 | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 85/132 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100089144, COSV60390358; called by muse, mutect2, varscan2
- FRAS1 | c.803C>T p.A268V | Missense Mutation (SNP) | VAF 8/109 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV53623785; called by muse, mutect2
- GATA1 | c.14G>T p.G5V | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.96); catalogued as COSV100936779; called by muse, mutect2, varscan2
- GPHN | c.235C>T p.L79F | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV100016237; called by muse, mutect2
- GPM6B | c.568C>T p.R190* | Nonsense Mutation (SNP) | VAF 27/77 reads (35%) | catalogued as rs770782854, COSV100366203; called by muse, mutect2, varscan2
- GRIA4 | c.2449G>A p.V817I | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.895); catalogued as rs752387055, COSV56916896; called by muse, mutect2, varscan2
- HDAC6 | c.2239G>A p.D747N | Missense Mutation (SNP) | VAF 21/134 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100490795; called by muse, mutect2, varscan2
- HEMGN | c.1292G>T p.G431V | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.178); catalogued as COSV99412397; called by muse, mutect2, varscan2
- HOXC8 | c.626A>G p.N209S | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.197); catalogued as COSV99236685; called by muse, mutect2, varscan2
- HSPG2 | c.6419C>T p.S2140F | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.259); catalogued as COSV101020672; called by muse, mutect2, varscan2
- IGSF1 | c.1025G>A p.R342Q | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs748526007, COSV63836836, COSV63839773; called by muse, mutect2, varscan2
- ITGA8 | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs764251072, COSV100959178; called by muse, mutect2, varscan2
- ITSN1 | c.1316G>C p.R439P | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.381); catalogued as COSV101180514, COSV101180598; called by muse, mutect2, varscan2
- KIF1B | c.5173G>A p.V1725I (on ENST00000377086 / NM_001365952.1; = p.V1679I on NM_015074.3) | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs753477704, COSV55812870; called by muse, varscan2
- KIR3DL2 | c.115G>T p.V39L | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs965756637, COSV54390945; called by muse, mutect2, varscan2
- KLF5 | c.1102G>T p.E368* | Nonsense Mutation (SNP) | VAF 6/33 reads (18%) | catalogued as COSV100890542; called by muse, mutect2, varscan2
- LILRB4 | c.1070A>G p.Q357R (on ENST00000391733 / NM_001278428.3; = p.Q356R on NM_001278426.3) | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.013); catalogued as COSV99553794; called by muse, mutect2
- LRATD2 | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 11/157 reads (7%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.984); catalogued as COSV100513577; called by muse, mutect2
- LRIG2 | c.2533G>A p.E845K | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV63165003; called by muse, mutect2, varscan2
- LRP1 | c.4738G>A p.E1580K | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.971); catalogued as COSV99675754; called by muse, mutect2, varscan2
- LRP6 | c.4335G>A p.M1445I | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV53783800; called by muse, mutect2, varscan2
- LRRC8A | c.1789G>C p.E597Q | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.209); catalogued as COSV99396570; called by muse, mutect2, varscan2
- LRTM1 | c.226C>T p.L76F | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99836037; called by muse, mutect2, varscan2
- MAP10 | c.2885C>G p.S962C | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.132); catalogued as COSV101406497; called by muse, mutect2, varscan2
- MATR3 | c.1768G>C p.D590H | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.282); catalogued as COSV100735201; called by mutect2, varscan2
- NBEAL1 | c.5121G>T p.E1707D | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.277); catalogued as COSV101495679; called by muse, mutect2, varscan2
- NCOA6 | c.2205T>A p.N735K | Missense Mutation (SNP) | VAF 53/113 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as COSV100750022; called by muse, mutect2, varscan2
- OGDHL | c.1399C>G p.P467A | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.764); catalogued as COSV100934308; called by muse, mutect2, varscan2
- OGFOD2 | c.622G>C p.D208H (on ENST00000228922 / NM_001304833.1; = p.D148H on NM_024623.3) | Missense Mutation (SNP) | VAF 4/82 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV99758884; called by muse, mutect2
- OPN4 | c.503G>C p.R168P | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV54119845, COSV99618349; called by muse, mutect2, varscan2
- OR5D18 | c.427G>A p.V143M | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as rs577643505, COSV61738236, COSV61738342; called by muse, mutect2, varscan2
- OSBPL9 | c.379G>A p.D127N | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100543369; called by muse, mutect2, varscan2
- OVOL2 | c.674C>G p.T225S | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.69); PolyPhen benign (0.047); catalogued as COSV99602441; called by muse, mutect2, varscan2
- PARP14 | c.3109T>G p.L1037V | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV101506277; called by muse, mutect2, varscan2
- PATJ | c.1261G>T p.V421F | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768805115, COSV100334138; called by muse, mutect2, varscan2
- PCDHGA2 | c.671G>A p.G224D | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); catalogued as COSV53911697, COSV99537883; called by muse, mutect2, varscan2
- PENK | c.239G>T p.G80V | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.157); catalogued as COSV100152307; called by muse, mutect2, varscan2
- PHKA1 | c.357A>C p.K119N | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as COSV100263137; called by muse, mutect2
- PLA1A | c.911G>T p.C304F | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99845861; called by muse, mutect2, varscan2
- PLCD3 | c.704A>G p.N235S | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.079); catalogued as COSV100504230; called by muse, mutect2, varscan2
- PLEKHB2 | c.196C>T p.Q66* | Nonsense Mutation (SNP) | VAF 13/55 reads (24%) | catalogued as COSV52176109; called by muse, mutect2, varscan2
- PLIN5 | c.1085T>G p.L362R | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV101113508; called by muse, mutect2
- PMF1 | c.458A>G p.Q153R | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as COSV100196097; called by muse, mutect2, varscan2
- PPP4R3A | c.1328G>T p.G443V (on ENST00000554943 / NM_001366432.1; = p.G430V on NM_001284280.1) | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); catalogued as COSV100466037; called by muse, mutect2, varscan2
- PPP6R2 | c.1228G>T p.A410S | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0.046); catalogued as COSV99324198; called by muse, mutect2, varscan2
- PRR5L | c.862C>T p.R288W | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771531021, COSV100287023; called by muse, mutect2, varscan2
- PRRC2A | c.1345T>C p.W449R | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV100784578; called by muse, mutect2, varscan2
- PVRIG | c.454C>T p.P152S | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.42); PolyPhen benign (0.058); catalogued as COSV99443830; called by muse, mutect2, varscan2
- RBM42 | c.1319G>A p.R440H | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs753990775, COSV99387005; called by muse, mutect2, varscan2
- RIN2 | c.869G>C p.R290P (on ENST00000255006 / NM_001242581.1; = p.R241P on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV54789712, COSV54791096; called by muse, mutect2, varscan2
- SCN9A | c.2381A>C p.K794T (on ENST00000303354; = p.K783T on NM_002977.3) | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100312700; called by muse, mutect2, varscan2
- SEMA7A | c.769C>G p.L257V | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.051); catalogued as COSV99984765; called by muse, mutect2, varscan2
- SERTAD4 | c.1009C>T p.R337W | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs150924683; called by muse, mutect2
- SESN2 | c.1256G>A p.R419Q | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs764559704, COSV99455702; called by muse, mutect2, varscan2
- SOWAHA | c.1259G>A p.R420H | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774555951, COSV101097667; called by muse, varscan2
- SP7 | c.992G>T p.C331F | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100381997, COSV100382119; called by muse, mutect2, varscan2
- SPOCK1 | c.598G>A p.D200N | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.997); catalogued as rs979703011, COSV56436773, COSV56446354, COSV99968959; called by muse, mutect2, varscan2
- SYNPO | c.1623G>T p.R541S (on ENST00000394243 / NM_001166208.2; = p.R297S on NM_007286.6) | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV100302129; called by muse, mutect2
- TAAR6 | c.171C>G p.I57M | Missense Mutation (SNP) | VAF 7/151 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV99256676; called by muse, mutect2
- TEX10 | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.73); catalogued as rs774262520, COSV66519771; called by muse, mutect2, varscan2
- TNIP1 | c.1063G>C p.E355Q | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.685); catalogued as COSV100161309, COSV100161318; called by muse, mutect2, varscan2
- TOX3 | c.298A>G p.S100G | Missense Mutation (SNP) | VAF 31/41 reads (76%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as COSV99567535; called by muse, mutect2, varscan2
- TSC2 | c.838A>T p.M280L | Missense Mutation (SNP) | VAF 64/105 reads (61%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.817); catalogued as COSV54759312, COSV99554049; called by muse, mutect2, varscan2
- UNC45A | c.2546G>A p.R849Q | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs561364913, COSV101263212; called by muse, mutect2, varscan2
- UNC93A | c.1087del p.V363Sfs*56 | Frame Shift Del (DEL) | VAF 17/35 reads (49%) | catalogued as COSV57810717; called by mutect2, pindel, varscan2
- USH2A | c.10247G>T p.C3416F | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100234358; called by muse, mutect2, varscan2
- USH2A | c.929G>C p.R310P | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100234360, COSV56347017, COSV56379080; called by muse, mutect2, varscan2
- VRTN | c.68G>A p.G23D | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.975); catalogued as COSV99832236; called by muse, mutect2, varscan2
- WIZ | c.4591G>A p.A1531T (on ENST00000673675 / NM_001371589.1; = p.A436T on NM_021241.3) | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.065); catalogued as COSV99653191; called by muse, mutect2
- WNT2B | c.316G>A p.E106K (on ENST00000369684 / NM_024494.3; = p.E87K on NM_004185.4) | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99861644; called by muse, mutect2, varscan2
- WWC3 | c.1921C>T p.R641* | Nonsense Mutation (SNP) | VAF 12/44 reads (27%) | catalogued as COSV66507847; called by muse, mutect2, varscan2
- ZBED9 | c.2479G>C p.A827P | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101509235; called by muse, mutect2, varscan2
- ZNF248 | c.1057G>A p.D353N | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV100627606; called by muse, mutect2, varscan2
- ZNF276 | c.1581G>C p.E527D (on ENST00000443381 / NM_001113525.2; = p.E452D on NM_152287.4) | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs769486874, COSV99234899; called by muse, mutect2, varscan2
- ZNF670 | c.3+1G>C p.X1_splice | Splice Site (SNP) | VAF 4/56 reads (7%) | catalogued as COSV100829246; called by muse, mutect2
- IGHV1-58 | c.12T>G p.I4M | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.515); called by muse, mutect2, varscan2
- KDM3B | c.3170dup p.Y1057* | Nonsense Mutation (INS) | VAF 24/62 reads (39%) | called by mutect2, pindel, varscan2
- MUC2 | c.1999C>T p.H667Y | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT deleterious (0.02); called by muse, mutect2, varscan2
- OR11H1 | c.935C>G p.S312C | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.571); called by mutect2, varscan2
- PIK3R1 | c.426del p.G143Vfs*34 | Frame Shift Del (DEL) | VAF 22/67 reads (33%) | called by mutect2, pindel, varscan2
- PIK3R1 | c.1392_1403dup p.D464_Y467dup (on ENST00000521381 / NM_181523.3; = p.D194_Y197dup on NM_181504.4) | In Frame Ins (INS) | VAF 11/38 reads (29%) | called by mutect2, varscan2
- TP53 | c.483_502del p.I162Hfs*12 | Frame Shift Del (DEL) | VAF 25/36 reads (69%) | called by mutect2, pindel, varscan2
- ABCC10 | c.1752C>G p.A584= (on ENST00000372530 / NM_001198934.2; = p.A541= on NM_033450.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as COSV99767235; called by muse, mutect2, varscan2
- C2CD2 | c.1803C>T p.P601= | Silent (SNP) | VAF 43/92 reads (47%) | catalogued as rs766202785, COSV100297975, COSV61599574; called by muse, mutect2, varscan2
- CACNA1C | c.426G>C p.A142= | Silent (SNP) | VAF 14/69 reads (20%) | catalogued as COSV100218685; called by muse, mutect2, varscan2
- CHD8 | c.1080G>A p.S360= (on ENST00000646647 / NM_001170629.2; = p.S81= on NM_020920.4) | Silent (SNP) | VAF 44/300 reads (15%) | catalogued as rs769647344, COSV67870368; called by muse, mutect2, varscan2
- CYP2A6 | c.1473C>T p.F491= | Silent (SNP) | VAF 46/85 reads (54%) | catalogued as rs1282627188, COSV99991833; called by muse, mutect2, varscan2
- FAM118A | c.205C>T p.L69= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as rs1341991363, COSV99343569; called by muse, mutect2, varscan2
- GABRA2 | c.79C>T p.L27= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as COSV100734232, COSV62918399; called by muse, mutect2, varscan2
- GPR137B | c.489C>A p.L163= | Silent (SNP) | VAF 13/121 reads (11%) | catalogued as rs762446086, COSV100858339; called by muse, mutect2, varscan2
- GPR152 | c.276G>C p.R92= | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as COSV100351518; called by muse, mutect2, varscan2
- HRNR | c.7008T>A p.G2336= | Silent (SNP) | VAF 42/348 reads (12%) | catalogued as COSV100913439; called by muse, mutect2, varscan2
- IGKV1D-16 | c.132T>C p.T44= | Silent (SNP) | VAF 30/154 reads (19%) | catalogued as rs551065270; called by muse, mutect2, varscan2
- LRP1 | c.1143C>G p.V381= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as COSV99674451; called by muse, mutect2, varscan2
- MAGEC3 | c.600A>G p.Q200= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as COSV100025357; called by muse, mutect2, varscan2
- MAML3 | c.2073C>T p.H691= | Silent (SNP) | VAF 22/65 reads (34%) | catalogued as rs764960147, COSV100505176; called by muse, mutect2, varscan2
- MYLK | c.711C>T p.N237= | Silent (SNP) | VAF 35/82 reads (43%) | catalogued as rs149407805; ClinVar: likely benign / benign; called by muse, mutect2, varscan2
- PARP14 | c.2709C>G p.L903= | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as COSV101506276; called by muse, mutect2, varscan2
- PCDHB4 | c.1662C>T p.N554= | Silent (SNP) | VAF 7/115 reads (6%) | catalogued as rs782323296, COSV99522167; called by muse, mutect2
- PTPN20 | c.696G>C p.L232= | Silent (SNP) | VAF 34/196 reads (17%) | called by muse, mutect2, varscan2
- SERPINB5 | c.45G>T p.L15= | Silent (SNP) | VAF 12/67 reads (18%) | catalogued as COSV101237652; called by muse, mutect2, varscan2
- SLC16A13 | c.453C>T p.S151= | Silent (SNP) | VAF 34/85 reads (40%) | catalogued as COSV57275229; called by muse, mutect2, varscan2
- SLC30A10 | c.897C>T p.I299= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV100751501; called by muse, mutect2, varscan2
- SREBF2 | c.3000C>A p.T1000= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as COSV100761407, COSV63332001; called by muse, mutect2, varscan2
- TEX264 | c.612G>A p.G204= | Silent (SNP) | VAF 32/75 reads (43%) | catalogued as rs1396190444, COSV100392612, COSV100392663; called by muse, mutect2, varscan2
- TPPP | c.294C>T p.I98= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as rs149885066; called by muse, mutect2
- TRAV10 | c.180T>C p.D60= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as rs564931975; called by muse, mutect2, varscan2
- TTC4 | c.147G>A p.A49= | Silent (SNP) | VAF 33/59 reads (56%) | catalogued as rs779758970, COSV100988422, COSV64884695; called by muse, mutect2, varscan2
- UBR2 | c.561G>A p.V187= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as COSV100868541; called by muse, mutect2, varscan2
- AP3D1 | c.2602-1043G>C | Intron (SNP) | VAF 4/11 reads (36%) | catalogued as rs772098647, COSV100642660, COSV100642889; called by muse, varscan2
- ING1 | chr13:110714218 C>T | 5'Flank (SNP) | VAF 10/54 reads (19%) | catalogued as COSV58166583, COSV58167251; called by muse, mutect2, varscan2
